Gene-level copy-number profile of tumor specimen ALCH-B1R8-TTP1-A from ALCHEMIST case ALCH-B1R8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.8 years (24,383 days).
Specimen ALCH-B1R8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c1a91f5-2b3d-4445-8dcd-cc2b79ba0893.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1R8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/b64a3b2c-806c-4536-81c5-df92f0120e2f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,936; copy number 2: 54,735; copy number 3: 1,633; copy number 4: 55; copy number 5: 12; copy number 6: 2; copy number 7: 1; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:26,562,585–26,641,366, 2 genes, copy number 6: FAM166C, CIB4.
- chr2:95,297,327–95,386,077, 2 genes, copy number 5: KCNIP3, FABP7P2.
- chr16:33,808,778–33,810,767, 1 gene, copy number 7: AC136428.3.
- chr16:34,978,744–35,085,060, 6 genes, copy number 5 (within-gene range 2–5): LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.
- chr21:43,461,960–43,479,534, 1 gene, copy number 8 (within-gene range 4–8): LINC00313.

Autosomal genes at a single copy (total copy number 1): 1,912. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
